Somatic mutation profile of tumor specimen TCGA-06-0190-01A (aliquot TCGA-06-0190-01A-01D-1491-08) from TCGA case TCGA-06-0190, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 62.5 years (22,835 days).
Specimen TCGA-06-0190-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a6840004-7510-4282-980d-b7caf95b8c4a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0190-10B (Blood Derived Normal), aliquot TCGA-06-0190-10B-01D-1491-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3dffde20-6af0-47b0-9ff1-dbe52d973174

The open-access MAF lists 59 somatic variants for this specimen: 47 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 11, Splice Site 2, Nonsense Mutation 1, Frame Shift Del 1, RNA 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LRP2 | c.2639+1G>A p.X880_splice | Splice Site (SNP) | VAF 40/118 reads (34%) | catalogued as rs746752313, COSV55557161; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.276C>A p.D92E | Missense Mutation (SNP) | VAF 41/140 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779530981, CM033666, COSV64288954, COSV64292660; called by muse, mutect2, varscan2
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 9/65 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.2948C>T p.S983L (on ENST00000404938 / NM_001163941.2; = p.S538L on NM_178559.6) | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.613); catalogued as COSV51706637; called by muse, mutect2, varscan2
- ACTRT2 | c.823G>A p.G275R | Missense Mutation (SNP) | VAF 55/204 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201977075; called by muse, mutect2, varscan2
- ARHGEF5 | c.448G>T p.V150L | Missense Mutation (SNP) | VAF 48/363 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV99282816; called by muse, mutect2, varscan2
- ARRDC4 | c.854G>A p.C285Y | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.793); catalogued as COSV51419465; called by muse, mutect2
- BBX | c.2203+1G>T p.X735_splice | Splice Site (SNP) | VAF 26/119 reads (22%) | catalogued as COSV57886093; called by muse, mutect2, varscan2
- BRD4 | c.1278C>A p.F426L | Missense Mutation (SNP) | VAF 10/133 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54587335; called by muse, mutect2
- CC2D1A | c.1909C>T p.R637C | Missense Mutation (SNP) | VAF 50/246 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs761771153, COSV58784031; called by muse, varscan2
- CNTN6 | c.65T>A p.L22H | Missense Mutation (SNP) | VAF 50/177 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV63175010; called by muse, mutect2, varscan2
- CYP4F3 | c.943G>A p.D315N | Missense Mutation (SNP) | VAF 83/382 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.665); catalogued as rs780899134, COSV55407196; called by muse, mutect2, varscan2
- DNAAF1 | c.1183A>T p.S395C | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); catalogued as COSV57577571; called by muse, mutect2, varscan2
- DNAH5 | c.4163G>A p.G1388E | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54230814; called by muse, mutect2
- ECE2 | c.176C>T p.T59M | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as rs1228570426, COSV62566753; called by muse, mutect2, varscan2
- F5 | c.1600C>T p.R534* | Nonsense Mutation (SNP) | VAF 27/108 reads (25%) | catalogued as rs770011773, HM971410, COSV63120371; called by muse, mutect2, varscan2
- FECH | c.344G>A p.R115Q | Missense Mutation (SNP) | VAF 51/198 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs954889536, COSV50490464; called by muse, mutect2, varscan2
- FLG | c.7640C>T p.S2547L | Missense Mutation (SNP) | VAF 174/602 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.022); catalogued as rs369029216, COSV64242857; called by muse, mutect2, varscan2
- IGHG3 | c.922G>A p.A308T | Missense Mutation (SNP) | VAF 129/528 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs201961631; called by muse, mutect2, varscan2
- KCNG1 | c.1132G>A p.G378R | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100857083, COSV100857101; called by mutect2, varscan2
- KCNV1 | c.566G>A p.C189Y | Missense Mutation (SNP) | VAF 55/205 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.648); catalogued as COSV52086554; called by muse, mutect2, varscan2
- MBD1 | c.225G>A p.K75= | Splice Region (SNP) | VAF 21/68 reads (31%) | catalogued as COSV54002363; called by muse, mutect2, varscan2
- MYH8 | c.4259C>T p.T1420M | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs150344258; called by muse, mutect2, varscan2
- NF1 | c.1681T>C p.W561R | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62206292; called by muse, mutect2
- NIM1K | c.815G>A p.R272Q | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.782); catalogued as COSV58142365; called by muse, mutect2, varscan2
- NLRP12 | c.476G>A p.R159Q | Missense Mutation (SNP) | VAF 64/215 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.074); catalogued as rs1346585060, COSV60748912; called by muse, mutect2, varscan2
- NRK | c.2179C>T p.R727C | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.635); catalogued as rs751709929, COSV54598474; called by muse, mutect2
- NTNG2 | c.757C>T p.R253C | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1181589867, COSV62367184; called by muse, mutect2, varscan2
- OR4Q3 | c.529T>C p.F177L | Missense Mutation (SNP) | VAF 26/294 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as COSV59178913, COSV59180611; called by muse, mutect2
- PIAS4 | c.874G>A p.G292R | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV53679471; called by muse, mutect2
- PIK3CG | c.493G>A p.V165I | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs752602335, COSV63247110; called by muse, mutect2, varscan2
- PKN1 | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.078); catalogued as COSV99661221; called by muse, mutect2, varscan2
- RGL3 | c.1433C>T p.P478L | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.053); catalogued as rs370513538, COSV66506106; called by muse, mutect2, varscan2
- SERPING1 | c.1097G>A p.R366H | Missense Mutation (SNP) | VAF 77/197 reads (39%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as rs139000758, CD087121; called by muse, mutect2, varscan2
- SGO2 | c.1694C>A p.T565K | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as COSV63415730; called by muse, mutect2
- SLC12A7 | c.2876C>T p.A959V | Missense Mutation (SNP) | VAF 59/215 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as rs199620140; called by muse, mutect2, varscan2
- SLURP1 | c.11G>A p.R4H | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs377400398; called by muse, mutect2, varscan2
- TTLL12 | c.1219C>T p.R407W | Missense Mutation (SNP) | VAF 87/319 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763918205, COSV53355575; called by muse, mutect2, varscan2
- TTN | c.32062C>T p.P10688S (on ENST00000591111; = p.P9761S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/309 reads (23%) | PolyPhen benign (0.178); catalogued as rs758199108, COSV60068336; called by muse, mutect2, varscan2
- USP49 | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV51897841; called by muse, mutect2, varscan2
- ZBTB21 | c.2245G>A p.V749I | Missense Mutation (SNP) | VAF 136/547 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.271); catalogued as rs774567286, COSV60404382; called by muse, mutect2, varscan2
- ZCCHC4 | c.1346G>A p.G449D | Missense Mutation (SNP) | VAF 48/151 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV57181529; called by muse, mutect2, varscan2
- ZNF335 | c.1618C>T p.R540W | Missense Mutation (SNP) | VAF 51/175 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs780577772, COSV59817450; called by muse, mutect2, varscan2
- ZNF688 | c.704C>T p.S235F | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs201261814, COSV56301036; called by muse, mutect2, varscan2
- CDK13 | c.3296_3298del p.L1099del | In Frame Del (DEL) | VAF 24/176 reads (14%) | called by pindel, varscan2
- FCGBP | c.9176G>C p.R3059P | Missense Mutation (SNP) | VAF 24/306 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.023); called by muse, mutect2
- HAT1 | c.879_885del p.C294Ifs*10 | Frame Shift Del (DEL) | VAF 21/124 reads (17%) | called by mutect2, pindel, varscan2
- ANPEP | c.2037G>A p.A679= | Silent (SNP) | VAF 37/239 reads (15%) | catalogued as rs764127625, COSV100262844, COSV55592092; called by muse, mutect2, varscan2
- CDK13 | c.3303T>G p.S1101= | Silent (SNP) | VAF 31/186 reads (17%) | catalogued as COSV51701038; called by muse, varscan2
- COBL | c.1197G>A p.A399= | Silent (SNP) | VAF 33/140 reads (24%) | catalogued as rs770546382, COSV54348055; called by muse, mutect2, varscan2
- CSF2RA | c.231C>T p.N77= | Silent (SNP) | VAF 77/508 reads (15%) | catalogued as rs767927197, COSV62623442; called by muse, mutect2, varscan2
- CYLD | c.867G>A p.A289= | Silent (SNP) | VAF 25/94 reads (27%) | catalogued as rs778051762, COSV61095059; called by muse, mutect2, varscan2
- FGF20 | c.516C>T p.D172= | Silent (SNP) | VAF 26/324 reads (8%) | catalogued as rs376980441; called by muse, mutect2
- GABRA4 | c.1227T>C p.H409= | Silent (SNP) | VAF 38/131 reads (29%) | catalogued as COSV51929287; called by muse, mutect2, varscan2
- LIPE | c.2529G>A p.S843= | Silent (SNP) | VAF 11/83 reads (13%) | catalogued as rs770762145, COSV54923275; called by muse, mutect2, varscan2
- SIGLEC11 | c.1266G>A p.E422= | Silent (SNP) | VAF 26/160 reads (16%) | catalogued as COSV70222025, COSV70222129; called by muse, varscan2
- SNX1 | c.489A>G p.V163= | Silent (SNP) | VAF 48/160 reads (30%) | catalogued as COSV56038588; called by muse, mutect2, varscan2
- SPIC | c.528C>T p.Y176= | Silent (SNP) | VAF 33/137 reads (24%) | catalogued as rs759289491, COSV54690341; called by muse, mutect2, varscan2
- DCHS2 | n.602C>T | RNA (SNP) | VAF 39/124 reads (31%) | catalogued as COSV59728638; called by muse, mutect2, varscan2
